Somatic mutation profile of tumor specimen TCGA-YL-A8SR-01B (aliquot TCGA-YL-A8SR-01B-11D-A377-08) from TCGA case TCGA-YL-A8SR, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.3 years (23,488 days).
Specimen TCGA-YL-A8SR-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e2ba96f-ba08-4a87-8c26-cd85ceebc570.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SR-10A (Blood Derived Normal), aliquot TCGA-YL-A8SR-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d2720ff-3253-40d0-a3c8-34fbd1b8d2bf

The open-access MAF lists 22 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 17, Nonsense Mutation 2, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL4 | c.393C>G p.Y131* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100879489; called by muse, mutect2, varscan2
- ABCA7 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV99565863, COSV99566494; called by muse, mutect2, varscan2
- ABHD18 | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101180847; called by muse, mutect2, varscan2
- BLCAP | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99290180; called by muse, mutect2, varscan2
- C1S | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100196751; called by muse, mutect2, varscan2
- C1orf87 | c.291C>G p.N97K | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as COSV100967222; called by muse, mutect2, varscan2
- ERBB4 | c.1858A>G p.N620D | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV99630590; called by muse, mutect2, varscan2
- FAM89A | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV64166134; called by muse, mutect2, varscan2
- IGHV3-23 | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as rs782609850; called by muse, mutect2, varscan2
- MEX3C | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1335790219, COSV101346319; called by muse, mutect2, varscan2
- MPP2 | c.900A>T p.E300D (on ENST00000461854 / NM_001278372.2; = p.E276D on NM_005374.5) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs775269681, COSV99290742; called by muse, mutect2, varscan2
- NOL9 | c.1375A>T p.K459* | Nonsense Mutation (SNP) | VAF 9/147 reads (6%) | catalogued as COSV100891515; called by muse, mutect2
- OTOGL | c.1328G>T p.C443F (on ENST00000547103; = p.C434F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101509045; called by muse, mutect2, varscan2
- PNLDC1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs370436669, COSV51704949; called by muse, mutect2, varscan2
- POLR1A | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99808256; called by muse, mutect2
- SLC22A9 | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208179251, COSV99655028; called by muse, mutect2, varscan2
- TASOR2 | c.1618C>G p.L540V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60169399; called by muse, mutect2, varscan2
- TESPA1 | c.224T>A p.F75Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.135); catalogued as COSV100345545; called by muse, mutect2, varscan2
- XIRP1 | c.5203C>A p.P1735T | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100453886; called by muse, mutect2
- ZNF7 | c.1917dup p.E640* | Frame Shift Ins (INS) | VAF 12/114 reads (11%) | called by mutect2, varscan2
- ATP13A4 | c.1198A>C p.R400= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as COSV99795139; called by muse, varscan2
- IGSF6 | c.114A>G p.L38= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99193656; called by muse, mutect2, varscan2
